Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAF7, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAF7-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address:

E-mail

Date

Concerning

Summary pathology report

Left orchidectomy; seminoma; two nodules respectively diameter 4 cm and diameter 1.5 cm;
tumor confined to testis in available slides; no angio-invasion; no invasion in rete testis.

Date of procurement (= date of orchidectomy):

ICD O-3
Seminoma NOS 9061/3
Site @ Testis NOS C62.9
W 3/3/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file 3bc10720-e0ca-4fb2-aa37-1dc9acc93d19 (TCGA-2G-AAF7-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).